CCDI case PBCKIF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/acbab640-fb2d-4048-8303-cc77f233dccc

Demographics
Sex at birth: male.

Diagnoses (1)
1. Metastatic signet ring cell carcinoma: ICD-O-3 morphology code: 8490/6; Tissue or organ of origin: Gastrointestinal tract, NOS; Age at diagnosis: 8.8 years (3,229 days).

Biospecimens (3 samples)
- Sample 0DUB68: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUB87: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DUB9L: Tissue type: Tumor; Specimen type: Solid Tissue.
